Somatic mutation profile of tumor specimen TCGA-19-5956-01A (aliquot TCGA-19-5956-01A-11D-1696-08) from TCGA case TCGA-19-5956, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.6 years (19,591 days).
Specimen TCGA-19-5956-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c862c5d-c494-4633-af8f-43bc115af017.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-19-5956-10A (Blood Derived Normal), aliquot TCGA-19-5956-10A-01D-1696-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a873714-42c9-4cc4-88a7-6016f4cfa0e2

The open-access MAF lists 8,107 somatic variants for this specimen: 6,135 protein-altering or splice-affecting, 1,790 silent, 182 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5,271, Silent 1,790, Nonsense Mutation 600, Splice Site 161, Intron 76, RNA 65, Splice Region 49, Frame Shift Ins 34, 3'UTR 16, Frame Shift Del 12, 5'Flank 10, 5'UTR 9.

Variants (750 of 8,107; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGL | c.3682C>T p.R1228* | Nonsense Mutation (SNP) | VAF 17/73 reads (23%) | catalogued as rs113994131, CM960018, COSV54049415, COSV99649605; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APC | c.6610C>T p.R2204* | Nonsense Mutation (SNP) | VAF 62/120 reads (52%) | catalogued as rs752654519, COSV57326468, COSV99965912; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ASPM | c.9730C>T p.R3244* | Nonsense Mutation (SNP) | VAF 8/76 reads (11%) | catalogued as rs199422195, CM077231, COSV54130194; ClinVar: pathogenic; called by mutect2, varscan2
- BRCA1 | c.3097G>T p.E1033* | Nonsense Mutation (SNP) | VAF 57/274 reads (21%) | catalogued as rs273899698, COSV100524646, COSV58789807; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CFTR | c.2126G>A p.R709Q | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as rs397508342, CM024683, COSV50043054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CFTR | c.3908dup p.N1303Kfs*6 | Frame Shift Ins (INS) | VAF 34/77 reads (44%) | catalogued as rs397508637; ClinVar: not provided / pathogenic; called by mutect2, pindel, varscan2
- CWF19L1 | c.964+1G>A p.X322_splice | Splice Site (SNP) | VAF 21/85 reads (25%) | catalogued as rs587780326, CS1412266, COSV100821556; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CYP4V2 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 83/166 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199476201, CM114000, COSV101114927; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DMD | c.10108C>T p.R3370* | Nonsense Mutation (SNP) | VAF 67/73 reads (92%) | catalogued as rs104894787, CM084898, CS921169, COSV58909013; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EYA4 | c.454C>A p.L152I | Missense Mutation (SNP) | VAF 48/227 reads (21%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.801); catalogued as COSV62046082, COSV62054147; called by muse, mutect2, varscan2
- GBA | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs878853317, COSV100516396; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GJA1 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs267606844, CM040424, COSV99247102; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNAQ | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 40/82 reads (49%) | hotspot (GDC flag); catalogued as COSV54106777, COSV99680195; called by muse, mutect2, varscan2
- HADHB | c.210-1G>T p.X70_splice | Splice Site (SNP) | VAF 11/108 reads (10%) | catalogued as rs200777054, CS125814, CS1312161, COSV100502069; ClinVar: likely pathogenic; called by mutect2, varscan2
- INPP5K | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 114/265 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761612652, COSV100233827; ClinVar: pathogenic; called by muse, varscan2
- IRF6 | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 33/82 reads (40%) | catalogued as rs121434224, CM022390, CM092335, COSV100884042, COSV65419096, COSV65419721; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LPL | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs118204062, CM910265, CM962613, COSV100255676; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MFSD2A | c.536C>T p.S179L (on ENST00000372809 / NM_001136493.3; = p.S166L on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/140 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as rs1057517689, CM156368, COSV65686400; ClinVar: pathogenic; called by muse, varscan2
- MLH1 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 63/112 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs63751194, CM011411, CM064120, CS105415, COSV51615553, COSV51616044; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.3916C>T p.R1306* | Nonsense Mutation (SNP) | VAF 30/174 reads (17%) | catalogued as rs376576925, CM981381, COSV62193951; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PAX8 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs104893657, CM981477, COSV99639748; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PDGFRA | c.2524G>T p.D842Y | Missense Mutation (SNP) | VAF 53/216 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913265, COSV57269122, COSV57271881; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PEX1 | c.403C>T p.R135* | Nonsense Mutation (SNP) | VAF 34/143 reads (24%) | catalogued as rs201415996, COSV50395532; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PLEC | c.1674G>A p.S558= (on ENST00000322810 / NM_201380.4; = p.S448= on NM_000445.5) | Splice Region (SNP) | VAF 6/17 reads (35%) | catalogued as rs864309672, CS056126, COSV100515987; ClinVar: pathogenic; called by muse, mutect2
- PRKCI | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 24/91 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.957); catalogued as rs1388201066, COSV55517137, COSV55517929; called by muse, mutect2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 42/154 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 21/71 reads (30%) | catalogued as rs1114167674, CM110151, COSV64293312; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 17/133 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs121918454, CM013417, COSV61005613, COSV61008344, COSV61012146; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- RAB3GAP1 | c.1237-2A>G p.X413_splice | Splice Site (SNP) | VAF 19/55 reads (35%) | catalogued as rs1558792168, CS132102, COSV99921392; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RHBDF2 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs387907130, CM121145, COSV100489511; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SEC24D | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148676365; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC25A13 | c.1063C>T p.R355* | Nonsense Mutation (SNP) | VAF 18/75 reads (24%) | catalogued as rs758827458, CM090577, CM139590, COSV99673842; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- SLC45A2 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912621, CM040825, COSV99672894; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.981T>G p.Y327* | Nonsense Mutation (SNP) | VAF 34/86 reads (40%) | catalogued as rs879254077, COSV52678878, COSV52914365, COSV52993701; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 19/45 reads (42%) | hotspot (GDC flag); catalogued as rs866380588, COSV52660737, COSV52978302; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TTN | c.63718C>T p.R21240* (on ENST00000591111; = p.R13816* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 25/69 reads (36%) | catalogued as rs1213930919, COSV100620224; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.48820C>T p.R16274* (on ENST00000591111; = p.R8850* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 42/137 reads (31%) | catalogued as rs753333359, COSV60032613; ClinVar: likely pathogenic; called by muse, varscan2
- VPS13A | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 20/106 reads (19%) | catalogued as rs119477053, CM011918, COSV100653089; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.1267G>T p.D423Y | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV55297557; called by muse, mutect2, varscan2
- A2ML1 | c.2008G>T p.D670Y | Missense Mutation (SNP) | VAF 50/264 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as COSV100229159; called by muse, mutect2, varscan2
- A4GNT | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as COSV99367930; called by muse, mutect2, varscan2
- AASDH | c.1514T>G p.L505R | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52706337, COSV99221521; called by muse, mutect2, varscan2
- AASDHPPT | c.237G>T p.W79C | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99593364; called by muse, mutect2, varscan2
- ABCA1 | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs757062730, COSV101037296, COSV66064355; called by muse, mutect2
- ABCA12 | c.470G>A p.G157D | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.022); catalogued as COSV99790847; called by muse, mutect2, varscan2
- ABCA12 | c.271G>T p.D91Y | Missense Mutation (SNP) | VAF 69/112 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV55954144; called by muse, mutect2, varscan2
- ABCA13 | c.6532G>T p.A2178S | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV101330108; called by muse, mutect2
- ABCA2 | c.6550C>T p.R2184W (on ENST00000614293; = p.R2154W on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs967247891, COSV99687999; called by muse, mutect2, varscan2
- ABCA2 | c.5162G>A p.R1721Q (on ENST00000614293; = p.R1691Q on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.422); catalogued as rs752560250, COSV99688001; called by muse, mutect2, varscan2
- ABCA3 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs755333350, COSV57059510; called by mutect2, varscan2
- ABCA5 | c.3583C>T p.R1195* | Nonsense Mutation (SNP) | VAF 30/57 reads (53%) | catalogued as rs757075616, COSV67018893; called by muse, mutect2, varscan2
- ABCA5 | c.2924C>A p.T975N | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.773); catalogued as COSV101201191; called by muse, mutect2
- ABCA5 | c.1334G>T p.R445I | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs776278452, COSV67017350; called by muse, mutect2, varscan2
- ABCA7 | c.4198C>T p.R1400C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.696); catalogued as rs1052116028, COSV54026326; called by muse, mutect2, varscan2
- ABCA7 | c.5408G>A p.R1803H | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs143615723; called by muse, mutect2, varscan2
- ABCA8 | c.1288C>T p.R430* | Nonsense Mutation (SNP) | VAF 10/93 reads (11%) | catalogued as rs368751441; called by mutect2, varscan2
- ABCA9 | c.1090C>T p.L364F | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.03); catalogued as COSV60628006; called by muse, mutect2, varscan2
- ABCB11 | c.48G>T p.E16D | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV99792507; called by mutect2, varscan2
- ABCB5 | c.1859T>G p.V620G (on ENST00000404938 / NM_001163941.2; = p.V175G on NM_178559.6) | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV99328889; called by muse, varscan2
- ABCB5 | c.3475G>A p.G1159S (on ENST00000404938 / NM_001163941.2; = p.G714S on NM_178559.6) | Missense Mutation (SNP) | VAF 47/96 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs142824450; called by muse, mutect2, varscan2
- ABCB7 | c.668G>A p.R223Q (on ENST00000373394 / NM_001271696.3; = p.R224Q on NM_004299.6) | Missense Mutation (SNP) | VAF 33/37 reads (89%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV99503900; called by muse, mutect2, varscan2
- ABCC1 | c.1750G>A p.V584M | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368340485; called by muse, mutect2
- ABCC10 | c.199C>T p.R67C (on ENST00000372530 / NM_001198934.2; = p.R24C on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.543); catalogued as rs375497152; called by muse, varscan2
- ABCC12 | c.1693G>T p.E565* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | catalogued as COSV60916024; called by muse, mutect2, varscan2
- ABCC2 | c.1467C>A p.V489= | Splice Region (SNP) | VAF 16/68 reads (24%) | catalogued as COSV100966610; called by muse, mutect2
- ABCC3 | c.2671G>T p.D891Y | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV99559427; called by muse, mutect2, varscan2
- ABCC5 | c.3595G>T p.E1199* | Nonsense Mutation (SNP) | VAF 16/114 reads (14%) | catalogued as COSV99657171; called by muse, mutect2, varscan2
- ABCC5 | c.3394G>A p.A1132T | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as rs1229947303, COSV55590773; called by muse, mutect2, varscan2
- ABCC6 | c.2959C>T p.R987C | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761565275, COSV52740968, COSV99229098; called by muse, mutect2, varscan2
- ABCC9 | c.3315+1G>A p.X1105_splice | Splice Site (SNP) | VAF 43/113 reads (38%) | catalogued as COSV53975659, COSV99686267; called by muse, mutect2, varscan2
- ABCC9 | c.2758G>A p.E920K | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.334); catalogued as COSV99686269; called by muse, mutect2, varscan2
- ABCD2 | c.1878-1G>T p.X626_splice | Splice Site (SNP) | VAF 15/95 reads (16%) | catalogued as COSV100429630; called by muse, mutect2, varscan2
- ABCD2 | c.143G>A p.G48D | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100429633; called by muse, mutect2, varscan2
- ABCD3 | c.1096C>T p.R366* | Nonsense Mutation (SNP) | VAF 46/84 reads (55%) | catalogued as COSV100931411; called by muse, mutect2, varscan2
- ABCE1 | c.1760A>G p.E587G | Missense Mutation (SNP) | VAF 16/187 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV99668679; called by muse, mutect2
- ABCF3 | c.259C>A p.L87M | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99490726, COSV99491039; called by muse, mutect2, varscan2
- ABCG1 | c.1809G>A p.R603= | Splice Region (SNP) | VAF 32/53 reads (60%) | catalogued as COSV100494325; called by muse, mutect2, varscan2
- ABCG2 | c.1780G>T p.G594* | Nonsense Mutation (SNP) | VAF 47/112 reads (42%) | catalogued as COSV99419598, COSV99420058; called by muse, mutect2, varscan2
- ABCG2 | c.1504A>G p.K502E | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99419601; called by muse, mutect2, varscan2
- ABCG2 | c.565G>A p.G189R | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV52947523; called by muse, mutect2, varscan2
- ABCG4 | c.1709A>G p.Y570C | Missense Mutation (SNP) | VAF 25/218 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150237922; called by muse, mutect2, varscan2
- ABCG8 | c.317G>A p.S106N | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.141); catalogued as COSV99700014, COSV99700357; called by muse, mutect2, varscan2
- ABHD11 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 58/172 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.109); catalogued as rs374778806; called by muse, mutect2
- ABHD12 | c.315C>T p.F105= | Splice Region (SNP) | VAF 19/91 reads (21%) | catalogued as rs151069701; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABHD16A | c.1502G>A p.R501H | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.215); catalogued as rs1271413764, COSV65451551; called by muse, mutect2
- ABHD4 | c.56C>T p.T19M | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as rs1254531304, COSV99360554; called by muse, mutect2, varscan2
- ABHD4 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 47/67 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs949135495, COSV99360557; called by muse, mutect2, varscan2
- ABHD6 | c.122A>G p.Y41C | Missense Mutation (SNP) | VAF 66/138 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99917078; called by muse, mutect2, varscan2
- ABHD8 | c.1314G>T p.K438N | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs1471007929, COSV56043973, COSV99917310; called by muse, mutect2, varscan2
- ABI2 | c.656G>A p.R219H (on ENST00000295851 / NM_001375719.1; = p.R213H on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 80/145 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs746431938, COSV53696660, COSV99652293; called by muse, mutect2, varscan2
- ABL2 | c.2020G>T p.E674* (on ENST00000502732 / NM_007314.4; = p.E659* on NM_005158.5) | Nonsense Mutation (SNP) | VAF 218/481 reads (45%) | catalogued as COSV100772860; called by muse, mutect2, varscan2
- ABR | c.734G>T p.R245L (on ENST00000302538 / NM_021962.5; = p.R208L on NM_001092.5) | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99348264; called by muse, mutect2
- AC007040.2 | c.140A>G p.Y47C | Missense Mutation (SNP) | VAF 139/233 reads (60%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV99730484; called by muse, mutect2, varscan2
- AC126283.2 | c.1235T>C p.V412A | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as COSV101144545; called by muse, mutect2, varscan2
- AC126283.2 | c.103G>T p.A35S | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT tolerated (0.99); PolyPhen benign (0.007); catalogued as COSV101144546; called by muse, mutect2, varscan2
- AC139530.2 | c.386A>G p.H129R | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.81); catalogued as rs770001602, COSV100230351; called by muse, mutect2, varscan2
- ACAA2 | c.184-1G>T p.X62_splice | Splice Site (SNP) | VAF 8/46 reads (17%) | catalogued as COSV99551944; called by muse, mutect2, varscan2
- ACACB | c.1215C>T p.S405= | Splice Region (SNP) | VAF 13/22 reads (59%) | catalogued as rs148317452; called by muse, mutect2, varscan2
- ACAD10 | c.1264G>A p.V422I | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.713); catalogued as rs749444698, COSV100564377; called by mutect2, varscan2
- ACAD11 | c.2272G>A p.E758K | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369697472, COSV53895516; called by muse, mutect2, varscan2
- ACADM | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 41/210 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100897716; called by muse, mutect2, varscan2
- ACADM | c.1229T>G p.I410S | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as CM128334, COSV100897718; called by muse, mutect2, varscan2
- ACADSB | c.220G>T p.E74* | Nonsense Mutation (SNP) | VAF 30/78 reads (38%) | catalogued as COSV100715244; called by muse, mutect2, varscan2
- ACAN | c.5309C>A p.S1770Y | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100718622; called by muse, mutect2, varscan2
- ACAN | c.7614G>T p.Q2538H (on ENST00000560601 / NM_001369268.1; = p.Q2500H on NM_013227.3) | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV100613817; called by muse, mutect2
- ACAT2 | c.728C>T p.T243M | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as rs749659871, COSV58457863; called by muse, mutect2, varscan2
- ACAT2 | c.1094C>T p.T365I | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100364975; called by muse, mutect2, varscan2
- ACCSL | c.838G>A p.V280I | Missense Mutation (SNP) | VAF 93/421 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.26); catalogued as rs1218432586, COSV101122232; called by muse, mutect2, varscan2
- ACE | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.13); catalogued as rs930786156, COSV52003000; called by muse, varscan2
- ACER1 | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs80167519, COSV56836226; called by muse, mutect2, varscan2
- ACKR4 | c.629T>G p.V210G | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV99392275; called by muse, mutect2, varscan2
- ACMSD | c.913A>C p.I305L | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.291); catalogued as COSV99299290; called by muse, mutect2, varscan2
- ACOT11 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 46/78 reads (59%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs781051947, COSV100650455; called by muse, mutect2, varscan2
- ACOX3 | c.1628A>G p.D543G | Missense Mutation (SNP) | VAF 36/197 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as COSV100711998; called by muse, mutect2, varscan2
- ACP3 | c.749A>G p.H250R | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); catalogued as rs1209576850, COSV100313453; called by muse, mutect2
- ACP3 | c.1054C>T p.P352S | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100313459; called by muse, mutect2, varscan2
- ACRV1 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs768673984, COSV59754494; called by mutect2, varscan2
- ACSL4 | c.2011G>A p.V671I (on ENST00000340800 / NM_022977.2; = p.V630I on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100538745; called by muse, mutect2, varscan2
- ACSM2B | c.337C>A p.L113M | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV100312911; called by muse, mutect2, varscan2
- ACSS3 | c.1955G>A p.R652Q | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759707767, COSV54088493, COSV99699182; called by muse, mutect2, varscan2
- ACTL6A | c.436A>T p.I146F | Missense Mutation (SNP) | VAF 102/265 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.456); catalogued as COSV101199689; called by muse, varscan2
- ACTL6B | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV50514372; called by muse, mutect2, varscan2
- ACTL7B | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 75/155 reads (48%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.922); catalogued as rs770928741, COSV65928446; called by muse, mutect2, varscan2
- ACTL7B | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 64/127 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs141483172, COSV101012549, COSV65927569; called by muse, mutect2, varscan2
- ACTN2 | c.1261G>T p.E421* | Nonsense Mutation (SNP) | VAF 4/39 reads (10%) | catalogued as COSV63972751; called by muse, mutect2
- ACTN3 | c.2260G>A p.A754T | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as rs574848604, COSV100074366; called by mutect2, varscan2
- ACTR1B | c.865G>T p.D289Y | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100008145; called by muse, mutect2, varscan2
- ACTR8 | c.1189A>C p.T397P | Missense Mutation (SNP) | VAF 124/244 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as COSV99213799; called by muse, mutect2, varscan2
- ACTR8 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 102/254 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374119128; called by muse, mutect2, varscan2
- ACVR1C | c.1226-1G>T p.X409_splice | Splice Site (SNP) | VAF 13/69 reads (19%) | catalogued as COSV99694851; called by muse, mutect2, varscan2
- ACVR2A | c.1137G>T p.R379S | Missense Mutation (SNP) | VAF 54/207 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV54021727, COSV99604718; called by muse, mutect2, varscan2
- ACVR2B | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 61/256 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs759935727, COSV100754286; called by muse, mutect2, varscan2
- ACY3 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs768583318, COSV54828438; called by muse, mutect2, varscan2
- ADAL | c.633G>T p.E211D | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101052565; called by muse, mutect2, varscan2
- ADAM10 | c.1480A>C p.K494Q | Missense Mutation (SNP) | VAF 72/175 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.027); catalogued as COSV99546266; called by muse, mutect2, varscan2
- ADAM15 | c.514C>A p.L172I | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV55056362; called by muse, mutect2, varscan2
- ADAM17 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 44/69 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as rs869025265, COSV100176375; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADAM19 | c.2513G>A p.R838Q | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs1190633013, COSV57433028; called by muse, mutect2
- ADAM21 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV50789103; called by muse, mutect2, varscan2
- ADAM22 | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 14/173 reads (8%) | catalogued as COSV99717503; called by muse, mutect2
- ADAM23 | c.682G>A p.V228M | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.063); catalogued as rs199943814, COSV52213788; called by mutect2, varscan2
- ADAM28 | c.1634G>A p.R545H | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs1252057527, COSV99739190; called by muse, mutect2, varscan2
- ADAM32 | c.1097G>T p.S366I | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV101165401, COSV65950560; called by muse, mutect2, varscan2
- ADAM7 | c.1228T>G p.L410V | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99444350; called by muse, mutect2, varscan2
- ADAM8 | c.589C>T p.R197* | Nonsense Mutation (SNP) | VAF 12/65 reads (18%) | catalogued as rs774786953, COSV101291628, COSV101291689, COSV69864525; called by muse, mutect2, varscan2
- ADAMDEC1 | c.284+1G>T p.X95_splice | Splice Site (SNP) | VAF 17/73 reads (23%) | catalogued as COSV99836160; called by muse, varscan2
- ADAMTS12 | c.473G>A p.S158N | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV100711322; called by muse, varscan2
- ADAMTS12 | c.452G>T p.R151I | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.158); catalogued as COSV100711323, COSV61281512; called by muse, varscan2
- ADAMTS13 | c.2624C>T p.S875F | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV100747144, COSV63020302; called by muse, mutect2
- ADAMTS16 | c.1273C>A p.L425I | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99941954; called by muse, mutect2
- ADAMTS16 | c.1894C>A p.L632M | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV56993327, COSV99941073; called by muse, mutect2, varscan2
- ADAMTS17 | c.1690C>T p.R564C | Missense Mutation (SNP) | VAF 49/89 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs1292743986, COSV99171064; called by muse, mutect2, varscan2
- ADAMTS18 | c.1866G>T p.Q622H | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV99273458; called by muse, mutect2
- ADAMTS18 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as rs775057284, COSV51408503; called by muse, mutect2, varscan2
- ADAMTS2 | c.1712G>A p.G571D | Missense Mutation (SNP) | VAF 39/271 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99282959; called by muse, mutect2, varscan2
- ADAMTS3 | c.1379C>A p.P460H | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99711501; called by muse, mutect2, varscan2
- ADAMTS5 | c.1071G>T p.E357D | Missense Mutation (SNP) | VAF 69/168 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.166); catalogued as COSV99537922; called by muse, mutect2, varscan2
- ADAMTS6 | c.1471C>T p.R491C | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66860100; called by muse, mutect2, varscan2
- ADAMTS6 | c.19A>T p.T7S | Missense Mutation (SNP) | VAF 63/135 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV101125207; called by muse, mutect2, varscan2
- ADAMTS9 | c.1438C>T p.R480* | Nonsense Mutation (SNP) | VAF 28/122 reads (23%) | catalogued as COSV55778753; called by muse, mutect2, varscan2
- ADAMTS9 | c.1292C>T p.T431M | Missense Mutation (SNP) | VAF 125/281 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1265031681, COSV55779734; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 30/38 reads (79%) | SIFT tolerated (0.54); PolyPhen benign (0.049); catalogued as rs547340684, COSV99443758; called by muse, varscan2
- ADAMTSL1 | c.3232C>A p.L1078M | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV101001967; called by mutect2, varscan2
- ADAMTSL3 | c.4139C>A p.S1380Y | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV99719875; called by mutect2, varscan2
- ADCK5 | c.84C>A p.F28L | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.001); catalogued as COSV100450586; called by muse, mutect2, varscan2
- ADCY10 | c.3883G>A p.V1295M | Missense Mutation (SNP) | VAF 67/166 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as rs756898890, COSV100896953; called by muse, mutect2, varscan2
- ADCY10 | c.3753C>A p.I1251= | Splice Region (SNP) | VAF 39/87 reads (45%) | catalogued as COSV100896954; called by muse, mutect2, varscan2
- ADCY10 | c.3041T>A p.I1014N | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100896955; called by muse, mutect2
- ADCY5 | c.3204G>T p.E1068D | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.124); catalogued as COSV100567984; called by muse, mutect2, varscan2
- ADCY7 | c.2620T>G p.S874A | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99576196; called by muse, mutect2
- ADCYAP1R1 | c.1120G>T p.E374* | Nonsense Mutation (SNP) | VAF 20/140 reads (14%) | catalogued as COSV100416644; called by muse, mutect2, varscan2
- ADD2 | c.1562C>T p.A521V | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs373747708, COSV52464232; called by muse, mutect2
- ADGRA3 | c.1463A>C p.D488A | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV99293470; called by muse, mutect2, varscan2
- ADGRB2 | c.4723G>A p.E1575K (on ENST00000373658 / NM_001364857.2; = p.E1574K on NM_001294335.2) | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.119); catalogued as COSV99926542; called by muse, mutect2, varscan2
- ADGRB3 | c.1930-1G>A p.X644_splice | Splice Site (SNP) | VAF 11/25 reads (44%) | catalogued as COSV101000701; called by muse, mutect2, varscan2
- ADGRD1 | c.336G>T p.K112N | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV99896219; called by muse, mutect2
- ADGRD1 | c.2530-1G>A p.X844_splice | Splice Site (SNP) | VAF 22/37 reads (59%) | catalogued as COSV55460466; called by muse, mutect2, varscan2
- ADGRG4 | c.3848C>A p.S1283Y | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs377239456, COSV54957590, COSV54966049; called by muse, mutect2, varscan2
- ADGRG6 | c.3077C>T p.A1026V | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as COSV99747857; called by muse, mutect2, varscan2
- ADGRL2 | c.2465G>T p.S822I (on ENST00000370717 / NM_001366005.1; = p.S809I on NM_012302.4) | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99590103; called by muse, mutect2, varscan2
- ADGRL2 | c.3347C>T p.S1116L (on ENST00000370717 / NM_001366005.1; = p.S1103L on NM_012302.4) | Missense Mutation (SNP) | VAF 78/154 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV99590106; called by muse, mutect2, varscan2
- ADGRL3 | c.1738C>T p.R580C (on ENST00000506720 / NM_001322402.2; = p.R512C on NM_015236.6) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs1333641797, COSV101547261; called by muse, mutect2, varscan2
- ADGRL3 | c.2911C>T p.R971W (on ENST00000506720 / NM_001322402.2; = p.R903W on NM_015236.6) | Missense Mutation (SNP) | VAF 33/266 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747197228, COSV72230097; called by muse, mutect2, varscan2
- ADH1A | c.345C>T p.N115= | Splice Region (SNP) | VAF 34/115 reads (30%) | catalogued as rs1412779396, COSV52926005; called by muse, mutect2, varscan2
- ADH6 | c.723C>A p.C241* | Nonsense Mutation (SNP) | VAF 136/791 reads (17%) | catalogued as COSV99422570; called by muse, mutect2, varscan2
- ADH7 | c.392G>A p.G131D | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.275); catalogued as COSV99265339; called by muse, mutect2
- ADM | c.215A>G p.D72G | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.478); catalogued as COSV99534266; called by muse, mutect2, varscan2
- ADNP2 | c.624G>T p.K208N | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.663); catalogued as COSV100081017, COSV51539110; called by muse, mutect2, varscan2
- ADORA2A | c.1141C>A p.P381T | Missense Mutation (SNP) | VAF 14/15 reads (93%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as COSV100418084; called by muse, mutect2, varscan2
- ADPGK | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374477325; called by muse, mutect2, varscan2
- ADPRH | c.1055A>G p.D352G | Missense Mutation (SNP) | VAF 53/200 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.169); catalogued as COSV100813338; called by muse, mutect2, varscan2
- ADPRM | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs370126868; called by muse, varscan2
- ADPRM | c.131A>G p.Y44C | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65755167; called by muse, varscan2
- ADRA1B | c.890G>A p.G297D | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100140317; called by muse, mutect2, varscan2
- AEBP1 | c.2659C>T p.P887S | Missense Mutation (SNP) | VAF 118/275 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); catalogued as rs749808468, COSV99788934; called by muse, mutect2, varscan2
- AFAP1 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as rs759888877, COSV61793397, COSV61797122; called by muse, mutect2, varscan2
- AFAP1 | c.384G>T p.E128D | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.493); catalogued as COSV100631803; called by muse, mutect2, varscan2
- AFDN | c.2257A>C p.S753R | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV100653205; called by muse, mutect2, varscan2
- AFF2 | c.588C>A p.F196L | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60655918; called by muse, mutect2, varscan2
- AFF3 | c.3029C>T p.S1010L | Missense Mutation (SNP) | VAF 59/99 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as rs866769084, COSV57842940, COSV57859628; called by muse, mutect2, varscan2
- AFF3 | c.2629C>T p.R877W | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as rs190577667, COSV57838935; called by muse, mutect2, varscan2
- AFG1L | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs754472966, COSV100933956; called by muse, mutect2, varscan2
- AFM | c.1056G>A p.A352= | Splice Region (SNP) | VAF 23/94 reads (24%) | catalogued as rs141061547; called by muse, mutect2, varscan2
- AGA | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs572348048, COSV99219586; called by muse, mutect2
- AGAP4 | c.1222C>T p.R408W | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1332671749; called by mutect2, varscan2
- AGBL1 | c.2573G>T p.S858I | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV101223665; called by muse, mutect2
- AGBL5 | c.1919G>A p.R640Q | Missense Mutation (SNP) | VAF 80/136 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs145709465; called by muse, mutect2, varscan2
- AGFG1 | c.940G>T p.V314F | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.07); catalogued as COSV100028967; called by muse, mutect2, varscan2
- AGFG1 | c.1043G>A p.G348D | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV100028969; called by muse, mutect2, varscan2
- AGFG1 | c.1228G>A p.V410M | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.556); catalogued as COSV100028971; called by muse, mutect2, varscan2
- AGO2 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV99596045; called by muse, mutect2
- AGTPBP1 | c.2729G>A p.R910H (on ENST00000357081 / NM_001330701.2; = p.R870H on NM_015239.2) | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61270790; called by muse, mutect2, varscan2
- AGTRAP | c.34C>A p.L12I | Missense Mutation (SNP) | VAF 64/282 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0.033); catalogued as COSV100065409; called by muse, mutect2, varscan2
- AHCYL1 | c.479T>C p.V160A | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100779618; called by muse, mutect2, varscan2
- AHI1 | c.3226G>T p.D1076Y | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99663122; called by muse, mutect2, varscan2
- AHNAK | c.13476G>T p.E4492D | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.011); catalogued as COSV99948343; called by muse, mutect2, varscan2
- AHNAK | c.927G>T p.M309I | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.107); catalogued as COSV99948344; called by muse, mutect2, varscan2
- AHNAK2 | c.14090C>T p.S4697L | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.415); catalogued as rs377637525; called by muse, mutect2, varscan2
- AHNAK2 | c.6806A>C p.K2269T | Missense Mutation (SNP) | VAF 49/176 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.14); catalogued as COSV100318198; called by muse, mutect2, varscan2
- AHNAK2 | c.5137G>A p.A1713T | Missense Mutation (SNP) | VAF 122/234 reads (52%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.98); catalogued as rs367713112; called by muse, mutect2
- AHNAK2 | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs779902900, COSV60922721; called by muse, mutect2, varscan2
- AHSA1 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.207); catalogued as rs1179701148, COSV99376091; called by muse, mutect2, varscan2
- AHSA1 | c.822G>A p.W274* | Nonsense Mutation (SNP) | VAF 17/98 reads (17%) | catalogued as COSV99376092; called by muse, mutect2, varscan2
- AIDA | c.583+1G>A p.X195_splice | Splice Site (SNP) | VAF 36/95 reads (38%) | catalogued as COSV100388362; called by muse, mutect2, varscan2
- AIF1 | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 7/65 reads (11%) | catalogued as rs1262259044, COSV100559070; called by muse, mutect2, varscan2
- AJM1 | c.2099G>A p.R700H | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV56035055; called by muse, mutect2, varscan2
- AKAP10 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV99855500; called by muse, mutect2, varscan2
- AKAP11 | c.96G>T p.Q32H | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.022); catalogued as COSV99214105; called by muse, mutect2, varscan2
- AKAP11 | c.3716G>T p.R1239I | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.329); catalogued as rs764701996, COSV50293062, COSV99214108; called by muse, mutect2, varscan2
- AKAP13 | c.3761G>A p.R1254H | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as rs138629757; called by muse, mutect2
- AKAP17A | c.8C>A p.A3E | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV100002352, COSV58309519; called by muse, mutect2, varscan2
- AKAP6 | c.1177G>T p.G393* | Nonsense Mutation (SNP) | VAF 28/94 reads (30%) | catalogued as COSV99802243; called by muse, mutect2
- AKAP8 | c.1342C>T p.R448C | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs758017011, COSV54100871; called by muse, mutect2, varscan2
- AKAP8L | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1267121368, COSV101275695, COSV101275821; called by muse, mutect2, varscan2
- AKAP9 | c.7051C>A p.L2351I (on ENST00000359028; = p.L2327I on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100662649; called by muse, mutect2, varscan2
- AKAP9 | c.7492C>A p.L2498I (on ENST00000359028; = p.L2474I on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.116); catalogued as COSV100662650, COSV62348102; called by muse, mutect2, varscan2
- AKIRIN2 | c.490C>T p.R164* | Nonsense Mutation (SNP) | VAF 30/138 reads (22%) | catalogued as rs866740945, COSV100005250; called by muse, mutect2, varscan2
- AL645922.1 | c.2242G>A p.D748N | Missense Mutation (SNP) | VAF 137/277 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.227); catalogued as rs1291146038, COSV54962581; called by muse, mutect2, varscan2
- AL669918.1 | c.2025-6C>T | Splice Region (SNP) | VAF 22/87 reads (25%) | catalogued as rs778791940, COSV101441035; called by muse, mutect2, varscan2
- ALDH16A1 | c.2315C>T p.P772L | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs1249199316, COSV52618103, COSV99201340; called by muse, mutect2, varscan2
- ALDH1A2 | c.674T>G p.L225R | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99990926; called by muse, mutect2, varscan2
- ALDH1A3 | c.1258C>A p.L420M | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0.044); catalogued as COSV100320516; called by muse, mutect2, varscan2
- ALDH1B1 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 34/157 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.072); catalogued as rs770868005, COSV66620743; called by muse, mutect2, varscan2
- ALDH1L2 | c.2615A>T p.E872V | Missense Mutation (SNP) | VAF 53/239 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV99311169; called by muse, mutect2, varscan2
- ALDH9A1 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.821); catalogued as rs767836676, COSV100699278, COSV61340553; called by muse, mutect2, varscan2
- ALDOB | c.726G>T p.K242N | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV100878890; called by muse, mutect2, varscan2
- ALG10 | c.1242A>C p.E414D | Missense Mutation (SNP) | VAF 57/257 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99848234; called by muse, mutect2, varscan2
- ALG11 | c.882G>T p.E294D | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as COSV101584348; called by mutect2, varscan2
- ALG12 | c.329G>T p.G110V | Missense Mutation (SNP) | VAF 23/54 reads (43%) | PolyPhen possibly damaging (0.506); catalogued as COSV100427159; called by muse, mutect2, varscan2
- ALG13 | c.2169G>T p.Q723H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV99322603; called by muse, mutect2, varscan2
- ALG2 | c.1111G>T p.E371* | Nonsense Mutation (SNP) | VAF 11/122 reads (9%) | catalogued as COSV99445601; called by muse, mutect2
- ALK | c.729G>A p.W243* | Nonsense Mutation (SNP) | VAF 24/144 reads (17%) | catalogued as COSV101202339; called by muse, mutect2, varscan2
- ALKAL1 | c.191-1G>T p.X64_splice | Splice Site (SNP) | VAF 6/33 reads (18%) | catalogued as rs1482216329, COSV100660229, COSV62131065; called by muse, mutect2, varscan2
- ALKBH1 | c.1110C>A p.F370L | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as COSV99380684; called by muse, mutect2, varscan2
- ALKBH6 | c.260C>T p.S87L (on ENST00000252984 / NM_001297701.2; = p.S115L on NM_032878.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV99431188; called by muse, mutect2, varscan2
- ALKBH7 | c.334C>A p.L112M | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99831760; called by muse, mutect2, varscan2
- ALMS1 | c.1428A>T p.K476N | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.15); catalogued as COSV100042986; called by muse, mutect2, varscan2
- ALMS1 | c.2721C>A p.F907L | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV100042988, COSV52518611; called by muse, mutect2, varscan2
- ALOX12 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT tolerated (0.2); PolyPhen benign (0.038); catalogued as COSV52350970; called by muse, mutect2, varscan2
- ALOX12B | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.3); catalogued as COSV100047432; called by muse, mutect2
- ALOX15 | c.1951C>A p.L651M | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV99541548; called by muse, mutect2, varscan2
- ALPK2 | c.4783C>T p.R1595C | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs572176995, COSV64493456; called by muse, varscan2
- ALPK2 | c.3046G>A p.E1016K | Missense Mutation (SNP) | VAF 110/198 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs184186856, COSV100864540; called by muse, mutect2, varscan2
- ALPK3 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374922996; called by mutect2, varscan2
- ALPK3 | c.4187G>A p.G1396D | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99361391; called by muse, mutect2
- ALPK3 | c.4788G>T p.K1596N | Missense Mutation (SNP) | VAF 57/189 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1281995273, COSV99361394; called by muse, mutect2, varscan2
- AMELX | c.554C>T p.T185I | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV100498528; called by muse, mutect2, varscan2
- AMER2 | c.1789C>T p.R597* | Nonsense Mutation (SNP) | VAF 28/138 reads (20%) | catalogued as COSV63437727; called by muse, mutect2, varscan2
- AMER2 | c.1294G>A p.D432N | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); catalogued as COSV100766315; called by muse, mutect2, varscan2
- AMFR | c.969G>T p.E323D | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV99316075; called by muse, mutect2, varscan2
- AMPD1 | c.1326G>T p.E442D | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100815110; called by muse, mutect2, varscan2
- AMPD1 | c.106C>A p.L36M | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.258); catalogued as COSV100815112, COSV62415135; called by muse, mutect2, varscan2
- AMPD3 | c.537G>T p.Q179H (on ENST00000396553 / NM_001025389.2; = p.Q188H on NM_000480.3) | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV101158202; called by muse, mutect2
- AMY2A | c.299G>T p.R100I | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101340648; called by muse, mutect2, varscan2
- AMY2B | c.558G>T p.E186D | Missense Mutation (SNP) | VAF 159/414 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV63717347; called by muse, mutect2, varscan2
- AMY2B | c.1141G>T p.V381L | Missense Mutation (SNP) | VAF 30/316 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100796382; called by muse, mutect2
- AMZ2 | c.75G>T p.Q25H | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.781); catalogued as COSV100703186; called by muse, mutect2, varscan2
- ANAPC2 | c.1376C>T p.T459I | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.229); catalogued as COSV100119151; called by muse, mutect2, varscan2
- ANAPC5 | c.2051C>A p.A684E | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99946333; called by muse, mutect2
- ANGPT2 | c.296A>C p.N99T | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as COSV100291045; called by muse, mutect2, varscan2
- ANGPTL3 | c.107G>T p.R36I | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99225083; called by muse, mutect2, varscan2
- ANK1 | c.994G>T p.D332Y | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55881770, COSV99225881; called by muse, mutect2, varscan2
- ANK2 | c.3361C>A p.L1121I | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100002676, COSV52150252; called by muse, mutect2, varscan2
- ANK2 | c.3571C>T p.R1191W | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771751897, COSV52150472; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK2 | c.10187C>A p.S3396Y | Missense Mutation (SNP) | VAF 87/212 reads (41%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.542); catalogued as COSV100002141, COSV52184715; called by muse, mutect2, varscan2
- ANK3 | c.12386C>A p.S4129Y (on ENST00000280772 / NM_001320874.2; = p.S650Y on NM_001149.3) | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55067894; called by muse, varscan2
- ANK3 | c.5740C>T p.R1914W | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1274185754, COSV99778439; called by muse, mutect2, varscan2
- ANKEF1 | c.1999C>A p.L667M | Missense Mutation (SNP) | VAF 53/109 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV101001046; called by muse, mutect2, varscan2
- ANKFN1 | c.2019C>A p.D673E | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100593821; called by muse, mutect2, varscan2
- ANKIB1 | c.1009A>G p.M337V | Missense Mutation (SNP) | VAF 162/354 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as rs1019336748, COSV99729439; called by muse, mutect2, varscan2
- ANKIB1 | c.3139C>A p.L1047M | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.022); catalogued as COSV99729441; called by muse, mutect2, varscan2
- ANKRD11 | c.7249G>A p.A2417T | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1205729029, COSV99969990; called by muse, mutect2, varscan2
- ANKRD11 | c.2398G>T p.E800* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as COSV99969994; called by muse, mutect2, varscan2
- ANKRD12 | c.2350G>T p.E784* | Nonsense Mutation (SNP) | VAF 28/102 reads (27%) | catalogued as COSV100041636; called by muse, mutect2, varscan2
- ANKRD12 | c.5785G>A p.E1929K | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100041638; called by muse, mutect2, varscan2
- ANKRD13B | c.564A>C p.Q188H | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as COSV101198924; called by muse, mutect2, varscan2
- ANKRD13C | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1406275483, COSV52029334; called by muse, mutect2, varscan2
- ANKRD26 | c.4517C>T p.A1506V | Missense Mutation (SNP) | VAF 26/37 reads (70%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.66); catalogued as rs775438679, COSV101063292; called by muse, mutect2, varscan2
- ANKRD30A | c.638T>C p.V213A (on ENST00000611781; = p.V157A on NM_052997.2) | Missense Mutation (SNP) | VAF 51/259 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.043); catalogued as COSV100653963, COSV64614707; called by muse, varscan2
- ANKRD30A | c.657G>T p.E219D (on ENST00000611781; = p.E163D on NM_052997.2) | Missense Mutation (SNP) | VAF 42/272 reads (15%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.874); catalogued as COSV64608110; called by muse, varscan2
- ANKRD30A | c.1573-1G>A p.X525_splice (on ENST00000611781; = p.X469_splice on NM_052997.2) | Splice Site (SNP) | VAF 22/133 reads (17%) | catalogued as COSV100653965, COSV64603630; called by muse, mutect2, varscan2
- ANKRD33 | c.7G>A p.A3T (on ENST00000340970 / NM_001304459.2; = p.A138T on NM_182608.4) | Missense Mutation (SNP) | VAF 59/127 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs145080334; called by muse, mutect2
- ANKRD33 | c.626C>T p.S209L (on ENST00000340970 / NM_001304459.2; = p.S334L on NM_182608.4) | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs373725055; called by muse, mutect2, varscan2
- ANKRD42 | c.1163A>G p.K388R | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV99473959; called by muse, mutect2, varscan2
- ANKRD52 | c.1484A>G p.Y495C | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.237); catalogued as COSV99921352; called by muse, mutect2, varscan2
- ANKRD52 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.427); catalogued as rs775597003, COSV99921249; called by muse, varscan2
- ANKS1B | c.2663C>A p.S888Y (on ENST00000547776 / NM_152788.4; = p.S114Y on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100228331; called by muse, mutect2, varscan2
- ANKS4B | c.239G>A p.C80Y | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.2); catalogued as COSV100289881; called by muse, mutect2, varscan2
- ANKS6 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.22); PolyPhen probably damaging (1); catalogued as rs557975586, COSV100782209, COSV62050384; called by muse, mutect2, varscan2
- ANO2 | c.1792G>A p.A598T (on ENST00000356134 / NM_001278597.3; = p.A602T on NM_001278596.3) | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.574); catalogued as rs748165730, COSV100501530; called by muse, mutect2, varscan2
- ANO3 | c.1448C>A p.A483D | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV99883882; called by muse, mutect2, varscan2
- ANO3 | c.2728C>A p.L910I | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.976); catalogued as COSV99883885; called by muse, mutect2, varscan2
- ANO3 | c.2839C>T p.R947* | Nonsense Mutation (SNP) | VAF 18/136 reads (13%) | catalogued as rs763228921, COSV56785203; called by muse, mutect2, varscan2
- ANO4 | c.326G>T p.G109V (on ENST00000392977 / NM_001286615.2; = p.G74V on NM_178826.4) | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV100153203, COSV54587459; called by muse, mutect2, varscan2
- ANO4 | c.1634A>G p.N545S (on ENST00000392977 / NM_001286615.2; = p.N510S on NM_178826.4) | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.696); catalogued as COSV54594182; called by muse, mutect2, varscan2
- ANO4 | c.1951G>T p.G651C (on ENST00000392977 / NM_001286615.2; = p.G616C on NM_178826.4) | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV100153205, COSV54597168; called by muse, mutect2, varscan2
- ANO5 | c.2194G>T p.D732Y | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.797); catalogued as COSV100202005; called by muse, mutect2, varscan2
- ANO6 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100263523; called by muse, mutect2, varscan2
- ANPEP | c.1065G>T p.E355D | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100263261; called by muse, mutect2, varscan2
- ANTKMT | c.695C>A p.S232Y | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.127); catalogued as COSV53495621; called by mutect2, varscan2
- ANXA1 | c.304G>T p.G102C | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57410752, COSV99973996; called by muse, mutect2, varscan2
- ANXA11 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.056); catalogued as rs535327650, COSV99627295; called by muse, mutect2, varscan2
- ANXA9 | c.784C>T p.L262F | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100929122; called by muse, mutect2, varscan2
- AOPEP | c.2069G>T p.R690I (on ENST00000375315 / NM_001193329.1; = p.R591I on NM_032823.5) | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as COSV99950221; called by muse, mutect2, varscan2
- AP001781.2 | c.617G>T p.R206I | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV99500047; called by muse, mutect2, varscan2
- AP002512.3 | c.644T>C p.V215A | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.101); catalogued as COSV99688025; called by muse, mutect2, varscan2
- AP1AR | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV56768735; called by muse, mutect2, varscan2
- AP1B1 | c.1345A>C p.I449L | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100434661; called by muse, mutect2, varscan2
- AP1G1 | c.429G>T p.E143D | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV100250666; called by muse, mutect2
- AP2A1 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs1401108451, COSV62821140; called by muse, mutect2, varscan2
- AP4B1 | c.1412C>T p.A471V | Missense Mutation (SNP) | VAF 104/215 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV99870953; called by muse, mutect2, varscan2
- AP4E1 | c.2459C>A p.S820Y | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.086); catalogued as COSV99956848; called by muse, mutect2, varscan2
- APAF1 | c.1805dup p.N602Kfs*24 (on ENST00000551964 / NM_181861.2; = p.N591Kfs*24 on NM_001160.3) | Frame Shift Ins (INS) | VAF 30/58 reads (52%) | catalogued as rs758129366; called by mutect2, varscan2
- APAF1 | c.2264A>G p.D755G (on ENST00000551964 / NM_181861.2; = p.D744G on NM_001160.3) | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.56); catalogued as COSV100244221; called by muse, mutect2, varscan2
- APBB1 | c.543G>T p.E181D | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100194174, COSV54975233; called by muse, mutect2, varscan2
- APBB3 | c.1317C>A p.S439R (on ENST00000357560 / NM_133173.2; = p.S446R on NM_006051.3) | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as rs768520917, COSV60365782; called by muse, mutect2, varscan2
- APC | c.3041T>C p.M1014T | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV99968821; called by muse, mutect2, varscan2
- APC | c.6676C>T p.R2226* | Nonsense Mutation (SNP) | VAF 13/132 reads (10%) | catalogued as rs1064794626, COSV57342370; called by muse, varscan2
- APH1B | c.319G>T p.G107C | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV99971570; called by muse, mutect2, varscan2
- APMAP | c.1096G>T p.E366* | Nonsense Mutation (SNP) | VAF 57/120 reads (48%) | catalogued as COSV99468817; called by muse, mutect2, varscan2
- APMAP | c.604G>T p.D202Y | Missense Mutation (SNP) | VAF 56/244 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751447454, COSV54177194, COSV99468822; called by muse, mutect2, varscan2
- APOH | c.614G>A p.C205Y | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99235851; called by muse, mutect2, varscan2
- APPL1 | c.2116G>T p.E706* | Nonsense Mutation (SNP) | VAF 18/145 reads (12%) | catalogued as COSV99897844; called by muse, mutect2, varscan2
- AQP3 | c.787C>A p.L263M | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs770798272, COSV99955627; called by muse, mutect2, varscan2
- AQP4 | c.962C>A p.S321Y | Missense Mutation (SNP) | VAF 93/204 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.593); catalogued as COSV101270539; called by muse, mutect2, varscan2
- AQP7 | c.691C>A p.L231M | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as COSV99953104; called by muse, mutect2, varscan2
- ARAP1 | c.3236G>A p.R1079Q (on ENST00000393609 / NM_001040118.2; = p.R834Q on NM_015242.4) | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as rs186025175; called by mutect2, varscan2
- ARF4 | c.334C>A p.L112M | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as COSV100327207; called by muse, mutect2, varscan2
- ARFGEF1 | c.4811C>T p.S1604F | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV51608061; called by muse, mutect2, varscan2
- ARFGEF1 | c.2656G>T p.E886* | Nonsense Mutation (SNP) | VAF 9/52 reads (17%) | catalogued as COSV99143108; called by muse, mutect2, varscan2
- ARFGEF1 | c.1484C>A p.S495* | Nonsense Mutation (SNP) | VAF 8/78 reads (10%) | catalogued as COSV51617964, COSV99143116; called by muse, mutect2, varscan2
- ARFGEF2 | c.4712C>T p.A1571V | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.716); catalogued as rs369538378; called by muse, mutect2, varscan2
- ARG1 | c.712C>A p.P238T | Missense Mutation (SNP) | VAF 71/139 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99256169; called by muse, mutect2, varscan2
- ARGFX | c.575A>C p.N192T | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV100544162; called by muse, mutect2, varscan2
- ARHGAP10 | c.1392-1G>T p.X464_splice | Splice Site (SNP) | VAF 126/361 reads (35%) | catalogued as COSV60599845; called by muse, mutect2, varscan2
- ARHGAP10 | c.1524G>T p.E508D | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.137); catalogued as COSV100331453; called by muse, mutect2, varscan2
- ARHGAP11A | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 31/119 reads (26%) | catalogued as COSV100853282, COSV64380589; called by muse, mutect2, varscan2
- ARHGAP11A | c.1289A>G p.K430R | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); catalogued as COSV100853283; called by muse, mutect2, varscan2
- ARHGAP12 | c.469G>A p.G157R | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.587); catalogued as rs760565918, COSV60966051; called by muse, mutect2, varscan2
- ARHGAP18 | c.1123-1G>A p.X375_splice | Splice Site (SNP) | VAF 20/37 reads (54%) | catalogued as rs4573108, COSV100936311; called by muse, mutect2, varscan2
- ARHGAP18 | c.131A>G p.Y44C | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100936312; called by muse, mutect2, varscan2
- ARHGAP19 | c.1480C>A p.L494I | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.031); catalogued as COSV100363247, COSV57394857; called by muse, mutect2, varscan2
- ARHGAP21 | c.4021G>T p.E1341* | Nonsense Mutation (SNP) | VAF 38/136 reads (28%) | catalogued as COSV100256411; called by muse, mutect2, varscan2
- ARHGAP21 | c.1712G>A p.R571Q | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs780035071, COSV100255958; called by muse, mutect2, varscan2
- ARHGAP25 | c.206T>C p.V69A (on ENST00000409202 / NM_001007231.3; = p.V62A on NM_014882.3) | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99771781; called by muse, varscan2
- ARHGAP26 | c.1426G>A p.A476T | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV99191181; called by muse, mutect2, varscan2
- ARHGAP30 | c.1891G>T p.G631W | Missense Mutation (SNP) | VAF 95/235 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.733); catalogued as COSV100920343, COSV63516186; called by muse, mutect2, varscan2
- ARHGAP31 | c.803G>A p.R268K | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV99957355; called by muse, mutect2, varscan2
- ARHGAP35 | c.3134C>A p.P1045H | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101351304; called by muse, mutect2, varscan2
- ARHGAP36 | c.748+1G>A p.X250_splice | Splice Site (SNP) | VAF 10/38 reads (26%) | catalogued as COSV99357899; called by muse, mutect2
- ARHGAP44 | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 31/98 reads (32%) | catalogued as COSV99310466; called by muse, mutect2, varscan2
- ARHGAP5 | c.664C>A p.L222I | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.978); catalogued as COSV100565519; called by muse, mutect2, varscan2
- ARHGAP5 | c.4502T>G p.I1501S (on ENST00000345122 / NM_001030055.2; = p.I1500S on NM_001173.3) | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); catalogued as COSV99391970; called by muse, mutect2, varscan2
- ARHGEF10 | c.83G>A p.R28Q (on ENST00000398564; = p.R4Q on NM_014629.4) | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.019); catalogued as rs777269503, COSV100034465; called by muse, mutect2, varscan2
- ARHGEF12 | c.2854G>A p.E952K | Missense Mutation (SNP) | VAF 48/94 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV100754915, COSV100755034; called by muse, mutect2, varscan2
- ARHGEF15 | c.2364G>T p.K788N | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100730078; called by muse, mutect2, varscan2
- ARHGEF18 | c.953C>A p.A318D (on ENST00000359920 / NM_001130955.2; = p.A214D on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100149721; called by mutect2, varscan2
- ARHGEF18 | c.1756G>A p.A586T (on ENST00000359920 / NM_001130955.2; = p.A482T on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs776929047, COSV60467331; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF26 | c.1030C>A p.L344M | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100726640, COSV62851557; called by muse, mutect2, varscan2
- ARHGEF28 | c.1692T>G p.I564M | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV99709514; called by muse, mutect2, varscan2
- ARHGEF37 | c.1990C>T p.R664W | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs745720450, COSV61369088; called by muse, mutect2, varscan2
- ARHGEF38 | c.469G>T p.E157* | Nonsense Mutation (SNP) | VAF 35/174 reads (20%) | catalogued as COSV99486410; called by muse, mutect2, varscan2
- ARHGEF39 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.803); catalogued as COSV100526284; called by muse, mutect2, varscan2
- ARHGEF40 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs369859283; called by muse, mutect2, varscan2
- ARHGEF7 | c.2518G>T p.D840Y (on ENST00000646102 / NM_001354046.1; = p.D624Y on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV99521820; called by muse, mutect2, varscan2
- ARID1A | c.4983G>T p.M1661I | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.065); catalogued as COSV100252363; called by muse, mutect2, varscan2
- ARID4B | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs771279053, COSV51598305; called by muse, mutect2, varscan2
- ARID4B | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as COSV51613820; called by muse, mutect2, varscan2
- ARL13B | c.562C>A p.H188N (on ENST00000394222 / NM_001174150.2; = p.H81N on NM_144996.4) | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as COSV100115608; called by muse, mutect2, varscan2
- ARL14 | c.227G>A p.G76D | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100296511; called by muse, mutect2, varscan2
- ARL14 | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1394056850, COSV57900042; called by muse, mutect2, varscan2
- ARL6IP5 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.703); catalogued as rs746762798, COSV99832986; called by muse, mutect2, varscan2
- ARMC5 | c.2342G>T p.S781I | Missense Mutation (SNP) | VAF 31/42 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV99192630; called by muse, mutect2, varscan2
- ARMC8 | c.1624C>T p.R542C (on ENST00000469044 / NM_001363941.2; = p.R528C on NM_015396.6) | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV58618719; called by muse, mutect2, varscan2
- ARMC8 | c.1720G>A p.E574K (on ENST00000469044 / NM_001363941.2; = p.E560K on NM_015396.6) | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100509772; called by muse, mutect2, varscan2
- ARMCX3 | c.655T>G p.S219A | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV100362300; called by muse, mutect2, varscan2
- ARMH4 | c.1370-1G>T p.X457_splice | Splice Site (SNP) | VAF 25/100 reads (25%) | catalogued as COSV50770550; called by muse, mutect2, varscan2
- ARPC2 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99826780; called by muse, mutect2
- ARPP21 | c.431C>A p.S144Y | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99492504; called by muse, mutect2, varscan2
- ARPP21 | c.2051C>T p.S684F | Missense Mutation (SNP) | VAF 65/235 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV99492505; called by muse, mutect2, varscan2
- ARRB2 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as rs757321101, COSV99347137; called by muse, mutect2, varscan2
- ARRDC4 | c.742C>T p.R248* | Nonsense Mutation (SNP) | VAF 9/67 reads (13%) | catalogued as rs1167957038, COSV99164408; called by muse, mutect2, varscan2
- ARSF | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764639218, COSV100839546; called by muse, mutect2, varscan2
- ARSK | c.770C>A p.S257Y | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV101187557; called by muse, mutect2, varscan2
- ART4 | c.896C>A p.S299Y | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); catalogued as COSV99966934; called by muse, mutect2, varscan2
- ASAH2 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs146246912; called by muse, varscan2
- ASAH2 | c.57G>T p.M19I | Missense Mutation (SNP) | VAF 38/56 reads (68%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV100270016; called by muse, mutect2, varscan2
- ASAP2 | c.1169C>A p.S390Y | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99856463; called by muse, mutect2, varscan2
- ASB10 | c.585-1G>T p.X195_splice (on ENST00000420175 / NM_001142459.2; = p.X180_splice on NM_080871.4) | Splice Site (SNP) | VAF 6/35 reads (17%) | catalogued as COSV99318749; called by muse, mutect2, varscan2
- ASB15 | c.1712G>T p.R571I | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.127); catalogued as COSV99306777; called by muse, mutect2, varscan2
- ASB2 | c.1314G>A p.M438I | Missense Mutation (SNP) | VAF 55/92 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.381); catalogued as COSV100279437; called by muse, mutect2, varscan2
- ASB4 | c.941A>C p.H314P | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV100367226; called by muse, mutect2
- ASH1L | c.3962G>A p.R1321Q | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.921); catalogued as rs1358026443, COSV64205657; called by muse, mutect2, varscan2
- ASH1L | c.637G>T p.G213* | Nonsense Mutation (SNP) | VAF 73/139 reads (53%) | catalogued as COSV100853504; called by muse, mutect2, varscan2
- ASH1L | c.528G>T p.K176N | Missense Mutation (SNP) | VAF 24/324 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.104); catalogued as COSV100853505; called by muse, mutect2
- ASIC4 | c.1200C>A p.F400L (on ENST00000347842 / NM_182847.3; = p.F419L on NM_018674.6) | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99705110; called by muse, mutect2, varscan2
- ASIP | c.215C>A p.S72Y | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV100892074, COSV66588414; called by muse, mutect2, varscan2
- ASNS | c.428G>T p.R143I | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99446497; called by muse, mutect2, varscan2
- ASNS | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.616); catalogued as rs761983860, COSV99445964; called by muse, mutect2, varscan2
- ASNSD1 | c.104G>T p.S35I | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.523); catalogued as COSV99641274; called by muse, mutect2, varscan2
- ASPHD1 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as COSV58097098; called by muse, mutect2, varscan2
- ASPM | c.6242A>T p.K2081I | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.031); catalogued as COSV54126867, COSV99660713; called by muse, mutect2
- ASPM | c.2651A>T p.K884M | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99660715; called by muse, mutect2, varscan2
- ASPM | c.2561G>A p.R854H | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99660716; called by muse, mutect2, varscan2
- ASPM | c.1924T>C p.L642= | Splice Region (SNP) | VAF 24/96 reads (25%) | catalogued as COSV99660718; called by muse, mutect2
- ASTL | c.354G>T p.Q118H | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); catalogued as COSV100668397; called by muse, mutect2, varscan2
- ASXL1 | c.570C>A p.F190L | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.859); catalogued as COSV100040097; called by muse, mutect2, varscan2
- ASXL1 | c.3152G>A p.R1051H | Missense Mutation (SNP) | VAF 68/252 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.147); catalogued as rs771896604, COSV60123920; called by muse, mutect2, varscan2
- ASXL3 | c.6155C>A p.S2052Y | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.191); catalogued as COSV99325599; called by muse, mutect2, varscan2
- ASZ1 | c.874A>G p.T292A | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV99498123; called by muse, mutect2
- ASZ1 | c.683A>G p.H228R | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV99498125; called by muse, mutect2
- ATAD2 | c.2300C>A p.S767Y | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as COSV99784960; called by muse, mutect2, varscan2
- ATAD2B | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs757248671, COSV99478051; called by muse, mutect2, varscan2
- ATE1 | c.1209T>G p.Y403* | Nonsense Mutation (SNP) | VAF 16/73 reads (22%) | catalogued as COSV99817415; called by muse, mutect2, varscan2
- ATF1 | c.257C>A p.S86Y | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV100016161; called by mutect2, varscan2
- ATG2A | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs375650529; called by mutect2, varscan2
- ATG2B | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.357); catalogued as rs778368919, COSV100737778, COSV63421927; called by mutect2, varscan2
- ATG2B | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.46); catalogued as rs1445145372, COSV63425034; called by muse, mutect2, varscan2
- ATP10A | c.3631G>A p.A1211T | Missense Mutation (SNP) | VAF 47/183 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as rs774142875, COSV63517153, COSV63518435; called by muse, mutect2, varscan2
- ATP10B | c.3459C>A p.F1153L | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT tolerated (1); PolyPhen probably damaging (0.989); catalogued as COSV100515316; called by muse, mutect2, varscan2
- ATP10D | c.1110T>G p.F370L | Missense Mutation (SNP) | VAF 36/303 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.705); catalogued as COSV99905077; called by muse, mutect2, varscan2
- ATP11A | c.1847T>G p.L616R | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV52116153, COSV99369235; called by muse, mutect2, varscan2
- ATP11A | c.3017C>T p.T1006M | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as rs551993113, COSV52105821; called by muse, mutect2, varscan2
- ATP11B | c.3368T>A p.F1123Y | Missense Mutation (SNP) | VAF 215/456 reads (47%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV100017935; called by muse, mutect2, varscan2
- ATP12A | c.2359C>A p.L787I | Missense Mutation (SNP) | VAF 75/162 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV99517988; called by muse, mutect2, varscan2
- ATP13A1 | c.3346G>A p.A1116T | Missense Mutation (SNP) | VAF 45/222 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as rs771899255, COSV52283199; called by muse, mutect2, varscan2
- ATP13A4 | c.381+2T>C p.X127_splice | Splice Site (SNP) | VAF 74/115 reads (64%) | catalogued as COSV99794827; called by muse, mutect2, varscan2
- ATP13A5 | c.1272+1G>T p.X424_splice | Splice Site (SNP) | VAF 11/59 reads (19%) | catalogued as COSV100665383; called by muse, mutect2, varscan2
- ATP1A4 | c.87A>C p.K29N | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV100927598; called by muse, varscan2
- ATP1B3 | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 51/220 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99657386; called by muse, mutect2, varscan2
- ATP1B4 | c.604C>T p.P202S (on ENST00000218008 / NM_001142447.3; = p.P198S on NM_012069.5) | Missense Mutation (SNP) | VAF 45/83 reads (54%) | SIFT tolerated (0.81); PolyPhen benign (0.277); catalogued as COSV99486417; called by muse, mutect2, varscan2
- ATP2B1 | c.2200C>A p.L734I | Missense Mutation (SNP) | VAF 61/255 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV99665896; called by muse, mutect2, varscan2
- ATP2B4 | c.2221G>T p.E741* | Nonsense Mutation (SNP) | VAF 31/266 reads (12%) | catalogued as COSV100397760; called by muse, mutect2, varscan2
- ATP4A | c.3093G>T p.Q1031H | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99382808; called by muse, mutect2, varscan2
- ATP4A | c.2081G>A p.R694H | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.553); catalogued as rs904563816, COSV52871892; called by muse, varscan2
- ATP4A | c.737G>A p.S246N | Missense Mutation (SNP) | VAF 65/161 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99382814; called by muse, mutect2, varscan2
- ATP5F1C | c.638-1G>T p.X213_splice | Splice Site (SNP) | VAF 12/52 reads (23%) | catalogued as COSV100184359, COSV100184420; called by muse, mutect2, varscan2
- ATP5MC1 | c.110C>A p.S37Y | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV100582399; called by muse, varscan2
- ATP5MC1 | c.409T>C p.*137Rext*28 | Nonstop Mutation (SNP) | VAF 73/134 reads (54%) | catalogued as COSV100582401; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1177G>T p.E393* | Nonsense Mutation (SNP) | VAF 92/192 reads (48%) | catalogued as COSV100376747; called by muse, mutect2, varscan2
- ATP6V0A4 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.122); catalogued as rs375991138; called by muse, mutect2, varscan2
- ATP7A | c.3504G>T p.Q1168H | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100431216; called by muse, mutect2, varscan2
- ATP7B | c.589C>T p.L197F | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs745909234, COSV99666645; called by muse, mutect2, varscan2
- ATP8A1 | c.2972C>A p.T991N | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.228); catalogued as COSV100046643; called by muse, mutect2, varscan2
- ATP8A2 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99682828; called by muse, mutect2, varscan2
- ATP8A2 | c.2956+2T>C p.X986_splice | Splice Site (SNP) | VAF 13/91 reads (14%) | catalogued as rs774105637, COSV99682834; called by muse, mutect2, varscan2
- ATP8B1 | c.853A>C p.S285R | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV99377498; called by muse, mutect2, varscan2
- ATP9A | c.2637G>T p.G879= | Splice Region (SNP) | VAF 30/55 reads (55%) | catalogued as COSV100125257; called by muse, mutect2, varscan2
- ATP9B | c.1618C>T p.R540* | Nonsense Mutation (SNP) | VAF 42/80 reads (53%) | catalogued as rs372536187; called by muse, mutect2, varscan2
- ATP9B | c.2283+1G>A p.X761_splice | Splice Site (SNP) | VAF 63/102 reads (62%) | catalogued as rs767092005, COSV100303846; called by muse, mutect2, varscan2
- ATP9B | c.3328G>T p.V1110L | Missense Mutation (SNP) | VAF 80/208 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs573183380, COSV100303847; called by muse, mutect2, varscan2
- ATR | c.2108T>C p.V703A | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100638366; called by muse, mutect2
- ATR | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs368507270, COSV63385058; called by mutect2, varscan2
- ATRNL1 | c.3420G>A p.S1140= | Splice Region (SNP) | VAF 15/31 reads (48%) | catalogued as rs776297873, COSV58074963, COSV58099812; called by muse, mutect2, varscan2
- ATRX | c.6947T>A p.L2316Q | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100971123; called by muse, mutect2
- ATRX | c.6160C>A p.L2054I | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV100971124; called by muse, mutect2, varscan2
- ATRX | c.4441C>T p.R1481W | Missense Mutation (SNP) | VAF 66/170 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100970390, COSV64880586; called by muse, varscan2
- ATRX | c.4396G>T p.E1466* | Nonsense Mutation (SNP) | VAF 118/132 reads (89%) | catalogued as COSV100971128; called by muse, varscan2
- ATRX | c.196A>G p.S66G | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.152); catalogued as COSV100969571; called by muse, mutect2, varscan2
- ATXN2 | c.2162C>T p.A721V (on ENST00000550104; = p.A561V on NM_002973.4) | Missense Mutation (SNP) | VAF 189/387 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.123); catalogued as COSV101112843; called by muse, mutect2, varscan2
- ATXN2 | c.1219G>T p.E407* (on ENST00000550104; = p.E247* on NM_002973.4) | Nonsense Mutation (SNP) | VAF 18/44 reads (41%) | catalogued as COSV101112846; called by muse, mutect2, varscan2
- ATXN3 | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as rs200118135, COSV100515431; called by muse, mutect2, varscan2
- ATXN3L | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 27/140 reads (19%) | catalogued as COSV66076212; called by muse, mutect2, varscan2
- ATXN3L | c.344A>C p.N115T | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101019488; called by muse, mutect2, varscan2
- ATXN7 | c.2255C>A p.S752Y | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.312); catalogued as COSV99894763; called by muse, mutect2, varscan2
- ATXN7L2 | c.1658C>A p.A553D | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV100149882; called by muse, varscan2
- AUNIP | c.793A>C p.S265R | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as COSV100961905; called by muse, mutect2, varscan2
- AURKA | c.1008G>T p.E336D | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.6); catalogued as COSV100453093; called by muse, mutect2, varscan2
- AXDND1 | c.2047A>C p.I683L | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100858521; called by muse, mutect2, varscan2
- AXIN1 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 52/95 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV51984069; called by muse, mutect2, varscan2
- AXL | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.71); catalogued as rs1255166048, COSV99996844; called by muse, mutect2
- B3GAT1 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100438074; called by muse, mutect2, varscan2
- B4GALT2 | c.1010A>G p.D337G | Missense Mutation (SNP) | VAF 48/437 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100530846; called by muse, mutect2, varscan2
- B4GALT6 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1484637669, COSV52702424, COSV99380154; called by muse, mutect2, varscan2
- B9D1 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.585); catalogued as COSV99264989; called by muse, mutect2, varscan2
- BABAM2 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.18); catalogued as rs773629059, COSV59624470, COSV59630226, COSV59633919; called by muse, mutect2, varscan2
- BACE2 | c.558C>A p.F186L | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100160719, COSV100160958; called by muse, mutect2, varscan2
- BACE2 | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs550964462, COSV57742376; called by muse, mutect2, varscan2
- BACH1 | c.901A>C p.T301P | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.029); catalogued as rs148287786, COSV99728414; called by muse, mutect2, varscan2
- BACH1 | c.1749G>T p.Q583H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99728416; called by muse, mutect2, varscan2
- BACH2 | c.1711A>C p.M571L | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV100000156; called by muse, mutect2, varscan2
- BAG2 | c.518G>T p.R173I | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58098903; called by muse, mutect2, varscan2
- BAG4 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99781921; called by muse, mutect2, varscan2
- BAG6 | c.2945G>A p.R982H (on ENST00000676571; = p.R935H on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.58); PolyPhen benign (0.403); catalogued as COSV99277282; called by muse, mutect2, varscan2
- BAIAP2L1 | c.297G>T p.E99D | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as COSV99134415; called by muse, mutect2, varscan2
- BAIAP3 | c.1687G>T p.D563Y | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV99136296; called by muse, mutect2
- BAMBI | c.420G>T p.Q140H | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100977518, COSV100977534; called by muse, mutect2, varscan2
- BARD1 | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs780820468, COSV99639175; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BARHL1 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as rs1253855027, COSV55039266; called by muse, mutect2, varscan2
- BASP1 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV59473016; called by muse, mutect2, varscan2
- BAZ1A | c.601T>G p.L201V | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV100701184; called by muse, mutect2, varscan2
- BAZ1B | c.3841C>T p.R1281* | Nonsense Mutation (SNP) | VAF 64/128 reads (50%) | catalogued as COSV100289902; called by muse, mutect2, varscan2
- BAZ1B | c.2211T>G p.F737L | Missense Mutation (SNP) | VAF 48/94 reads (51%) | SIFT tolerated (0.71); PolyPhen benign (0.06); catalogued as COSV100289903; called by muse, mutect2, varscan2
- BAZ2A | c.3334C>T p.R1112W | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs752773077, COSV99466827; called by muse, mutect2, varscan2
- BAZ2B | c.1189A>G p.T397A | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV100600801; called by muse, mutect2, varscan2
- BBS12 | c.1631T>G p.F544C | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV58562304; called by muse, varscan2
- BBS7 | c.358G>T p.D120Y | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV52654200; called by muse, mutect2, varscan2
- BCAR3 | c.1138C>T p.R380W | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as rs779491839, COSV53077869, COSV99550963; called by muse, mutect2, varscan2
- BCAS3 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 33/252 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.964); catalogued as rs765556399, COSV66777467; called by muse, mutect2, varscan2
- BCL2L1 | c.604G>A p.E202K (on ENST00000307677 / NM_001317919.2; = p.E139K on NM_001191.4) | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as rs751979681, COSV100304769; called by muse, mutect2, varscan2
- BCL2L11 | c.526G>A p.E176K (on ENST00000393256 / NM_138621.5; = p.E116K on NM_006538.5) | Missense Mutation (SNP) | VAF 47/77 reads (61%) | SIFT tolerated (0.69); PolyPhen benign (0.054); catalogued as rs1170116948, COSV58029750; called by muse, mutect2, varscan2
- BCL2L13 | c.865T>G p.L289V | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100456319; called by muse, mutect2, varscan2
- BCL6 | c.1649G>A p.R550H | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.994); catalogued as rs147650939; called by mutect2, varscan2
- BCL6B | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 36/241 reads (15%) | catalogued as COSV99546442, COSV99546768; called by muse, mutect2, varscan2
- BCL7B | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV99790347; called by muse, mutect2, varscan2
- BCLAF1 | c.1039G>T p.V347L | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV100786356; called by muse, mutect2, varscan2
- BDP1 | c.5662G>T p.E1888* | Nonsense Mutation (SNP) | VAF 8/139 reads (6%) | catalogued as COSV62429921; called by muse, mutect2
- BDP1 | c.7588C>T p.R2530C | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs749535883, COSV100702719, COSV62428945; called by mutect2, varscan2
- BEND2 | c.1753-1G>T p.X585_splice | Splice Site (SNP) | VAF 21/43 reads (49%) | catalogued as COSV101192098; called by muse, mutect2, varscan2
- BEND2 | c.409A>C p.N137H | Missense Mutation (SNP) | VAF 76/89 reads (85%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV101192102; called by muse, mutect2, varscan2
- BEND3 | c.1424G>A p.R475H | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.103); catalogued as rs782303650, COSV100944636; called by muse, mutect2, varscan2
- BEND7 | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 65/203 reads (32%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs139297820; called by muse, mutect2, varscan2
- BEST1 | c.1354G>A p.A452T | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs1392588193, COSV99861351; called by muse, mutect2, varscan2
- BEST3 | c.51T>G p.F17L | Missense Mutation (SNP) | VAF 51/226 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99876286; called by muse, mutect2, varscan2
- BEX5 | c.266A>G p.Y89C | Missense Mutation (SNP) | VAF 70/77 reads (91%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as rs143243676, COSV100375066; called by muse, mutect2, varscan2
- BFSP1 | c.1245A>C p.E415D | Missense Mutation (SNP) | VAF 64/137 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.105); catalogued as COSV100925390; called by muse, mutect2, varscan2
- BHLHE40 | c.348G>T p.Q116H | Missense Mutation (SNP) | VAF 30/476 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.546); catalogued as COSV99848202; called by muse, mutect2
- BICD2 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT tolerated (0.8); PolyPhen benign (0.266); catalogued as rs770331418, COSV100794188; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BICRA | c.1685C>T p.A562V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as rs1230287750; called by mutect2, varscan2
- BIN1 | c.1660A>C p.N554H (on ENST00000316724 / NM_001320642.1; = p.N415H on NM_004305.4) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99388256; called by mutect2, varscan2
- BIN3 | c.267G>T p.M89I | Missense Mutation (SNP) | VAF 49/252 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.022); catalogued as COSV99374172; called by muse, mutect2, varscan2
- BIRC6 | c.1969T>G p.L657V | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.108); catalogued as COSV101428446; called by muse, mutect2, varscan2
- BIRC6 | c.3380A>C p.N1127T | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV101428447; called by muse, mutect2, varscan2
- BIRC6 | c.12132G>T p.E4044D | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as COSV101134347; called by muse, mutect2, varscan2
- BIRC6 | c.12653G>A p.R4218H | Missense Mutation (SNP) | VAF 56/203 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs775201281, COSV70208748; called by muse, mutect2, varscan2
- BIRC6 | c.13534G>T p.A4512S | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV101428080; called by muse, mutect2, varscan2
- BIRC6 | c.13862A>G p.Y4621C | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101428452; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2442G>T p.E814D | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV100863833; called by muse, mutect2, varscan2
- BLID | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 88/172 reads (51%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.05); catalogued as rs371252798; called by muse, mutect2, varscan2
- BLM | c.2287C>A p.L763I | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs896043726, COSV61926963; called by muse, mutect2
- BLMH | c.1252T>C p.Y418H | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99913180; called by muse, mutect2, varscan2
- BLMH | c.57T>A p.N19K | Missense Mutation (SNP) | VAF 76/160 reads (48%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV99913181; called by muse, mutect2, varscan2
- BLNK | c.795G>T p.Q265H | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as COSV56410174, COSV99814048; called by muse, mutect2, varscan2
- BLZF1 | c.52C>T p.R18* | Nonsense Mutation (SNP) | VAF 33/89 reads (37%) | catalogued as COSV100250700; called by muse, mutect2, varscan2
- BMP15 | c.23G>T p.R8I | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as rs781806618, COSV53141164; called by muse, mutect2, varscan2
- BMP2K | c.2023G>A p.E675K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.505); catalogued as COSV99785236; called by muse, mutect2, varscan2
- BMP2K | c.2625G>T p.K875N | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV99785239; called by muse, mutect2, varscan2
- BMP5 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 59/137 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); catalogued as rs371743666, COSV100895985, COSV63707374; called by muse, mutect2, varscan2
- BMP5 | c.832+2T>C p.X278_splice | Splice Site (SNP) | VAF 10/98 reads (10%) | catalogued as COSV100896118; called by muse, mutect2, varscan2
- BMPR2 | c.2650C>A p.L884M | Missense Mutation (SNP) | VAF 71/127 reads (56%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.798); catalogued as COSV101001570; called by muse, mutect2, varscan2
- BMS1 | c.947C>A p.P316H | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100996752; called by muse, mutect2
- BMS1 | c.2667G>T p.E889D | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100996753; called by muse, mutect2, varscan2
- BMT2 | c.755C>A p.S252Y | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51775822, COSV51775977, COSV99774725; called by muse, mutect2, varscan2
- BMX | c.168A>C p.E56D | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100564548; called by mutect2, varscan2
- BMX | c.2008C>T p.R670W | Missense Mutation (SNP) | VAF 159/170 reads (94%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as rs1029888196, COSV53023604; called by muse, mutect2, varscan2
- BNC1 | c.2030G>A p.R677H | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs527423780, COSV100597328; called by muse, mutect2, varscan2
- BNC2 | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs756459154, COSV101033320, COSV66149708; called by muse, mutect2, varscan2
- BNIP5 | c.1877G>T p.R626I | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.395); catalogued as COSV101465180; called by mutect2, varscan2
- BNIPL | c.229C>A p.L77M | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99639715; called by muse, mutect2, varscan2
- BOD1L1 | c.8903G>T p.R2968I | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99239819; called by muse, mutect2, varscan2
- BOD1L1 | c.7757C>A p.P2586H | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.188); catalogued as COSV99239822; called by muse, mutect2, varscan2
- BOP1 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 73/144 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0.054); catalogued as rs1019799117; called by muse, mutect2, varscan2
- BPIFA1 | c.515G>T p.R172M | Missense Mutation (SNP) | VAF 75/374 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs771400366, COSV100845649; called by muse, mutect2, varscan2
- BPNT1 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.327); catalogued as COSV100435730; called by muse, mutect2, varscan2
- BPTF | c.2833G>T p.E945* | Nonsense Mutation (SNP) | VAF 25/198 reads (13%) | catalogued as COSV58835826; called by muse, mutect2, varscan2
- BPTF | c.7825A>C p.T2609P | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs782403455, COSV100075322; called by muse, mutect2, varscan2
- BRAF | c.2242C>T p.P748S (on ENST00000288602 / NM_001374244.1; = p.P708S on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV56136742; called by muse, mutect2
- BRCA1 | c.4313C>T p.A1438V | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.071); catalogued as COSV100524644; called by muse, mutect2, varscan2
- BRCA1 | c.1148A>G p.N383S | Missense Mutation (SNP) | VAF 66/237 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs770090143, COSV58786598; called by muse, mutect2, varscan2
- BRCA2 | c.2918C>T p.S973L | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs397507296, COSV101204451; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.3826G>T p.E1276* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as COSV101204452, COSV99061732; called by muse, mutect2, varscan2
- BRCA2 | c.7135G>A p.G2379R | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.036); catalogued as COSV101204454; called by muse, mutect2, varscan2
- BRCA2 | c.7787G>A p.G2596E | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064795140, COSV101204455; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.8499G>T p.K2833N | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101203970, COSV101204456; called by mutect2, varscan2
- BRCA2 | c.10202C>T p.T3401M | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.847); catalogued as rs55853199, HM971469, COSV58414221; ClinVar: uncertain significance / likely benign / conflicting interpretations of pathogenicity; called by muse, varscan2
- BRD4 | c.161A>G p.N54S | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV99651013; called by muse, mutect2, varscan2
- BRINP3 | c.1106C>T p.A369V | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.692); catalogued as rs1280054860, COSV66537409; called by muse, varscan2
- BRIP1 | c.3463G>T p.G1155* | Nonsense Mutation (SNP) | VAF 6/84 reads (7%) | catalogued as COSV99370497; called by muse, mutect2
- BRIP1 | c.2173G>A p.V725I | Missense Mutation (SNP) | VAF 111/237 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as rs1236873736, COSV52005702; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRIP1 | c.1871C>T p.S624L | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587781321, CM1411623, COSV51998688; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRIP1 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 138/287 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.571); catalogued as rs149364097, CM053143, COSV99370501; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRPF1 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs889065158, COSV57406900; called by muse, mutect2, varscan2
- BRPF1 | c.2680T>C p.F894L | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV100121321; called by muse, mutect2
- BRWD1 | c.4148G>A p.R1383Q | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs753135578, COSV100313708; called by muse, mutect2, varscan2
- BRWD3 | c.1160C>T p.T387M | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs937178689, COSV64744346; called by muse, mutect2, varscan2
- BTAF1 | c.1631T>A p.L544* | Nonsense Mutation (SNP) | VAF 10/104 reads (10%) | catalogued as COSV99795526; called by muse, mutect2
- BTBD11 | c.3305C>T p.S1102F (on ENST00000280758 / NM_001018072.2; = p.S639F on NM_001017523.2) | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99776338; called by muse, mutect2, varscan2
- BTBD17 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs755336000, COSV100945204, COSV64730023; called by muse, mutect2, varscan2
- BTBD3 | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.028); catalogued as COSV99655979; called by muse, mutect2, varscan2
- BTBD7 | c.1561C>T p.R521* | Nonsense Mutation (SNP) | VAF 18/111 reads (16%) | catalogued as rs1017916547, COSV100597990, COSV58285585; called by muse, mutect2, varscan2
- BTG3 | c.112C>A p.L38I | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100336332; called by muse, mutect2, varscan2
- BTG4 | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 19/80 reads (24%) | catalogued as COSV100604561; called by muse, mutect2, varscan2
- BTG4 | c.138G>A p.W46* | Nonsense Mutation (SNP) | VAF 27/52 reads (52%) | catalogued as COSV100604563; called by muse, mutect2, varscan2
- BTN2A2 | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.111); catalogued as rs1156599160, COSV61859277; called by muse, mutect2, varscan2
- BUB1 | c.1355C>T p.T452M | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779959736, COSV100241421; called by muse, mutect2, varscan2
- C10orf120 | c.850C>A p.L284I | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.25); catalogued as COSV100271703; called by muse, mutect2, varscan2
- C10orf62 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV101035297; called by muse, mutect2, varscan2
- C10orf71 | c.676G>T p.E226* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | catalogued as COSV100110366; called by muse, mutect2, varscan2
- C10orf71 | c.1792G>A p.A598T | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs769272748, COSV60509325; called by muse, mutect2, varscan2
- C10orf90 | c.817G>A p.V273I | Missense Mutation (SNP) | VAF 63/122 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs1215727661, COSV99504499; called by muse, mutect2, varscan2
- C11orf1 | c.395C>A p.P132H | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV99500053; called by muse, mutect2, varscan2
- C11orf94 | c.191C>A p.P64H | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99571596; called by muse, mutect2, varscan2
- C12orf40 | c.793T>A p.S265T | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV100210250, COSV100210375; called by muse, mutect2, varscan2
- C12orf40 | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as rs749162690, COSV61133712; called by muse, mutect2, varscan2
- C12orf50 | c.794A>C p.K265T | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.385); catalogued as COSV100072343; called by muse, mutect2, varscan2
- C12orf50 | c.274G>T p.V92L | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100072345; called by muse, mutect2, varscan2
- C12orf71 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV101460534; called by muse, mutect2, varscan2
- C14orf39 | c.1607C>A p.S536Y | Missense Mutation (SNP) | VAF 32/246 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.748); catalogued as rs1207776999, COSV100407833; called by muse, mutect2, varscan2
- C14orf39 | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 18/59 reads (31%) | catalogued as COSV58779397, COSV58779744; called by muse, mutect2, varscan2
- C14orf93 | c.1115G>A p.R372K | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as COSV100136765; called by muse, mutect2, varscan2
- C16orf46 | c.472G>T p.A158S | Missense Mutation (SNP) | VAF 25/340 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100215383; called by muse, mutect2
- C16orf71 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs750228262, COSV100173027; called by muse, mutect2, varscan2
- C17orf64 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); catalogued as rs935939750, COSV99293545; called by muse, mutect2
- C17orf80 | c.427T>C p.S143P | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as COSV99278243; called by muse, mutect2, varscan2
- C18orf25 | c.863C>T p.T288I | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.361); catalogued as COSV99960113; called by muse, mutect2, varscan2
- C1GALT1 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 72/151 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as COSV99777610; called by muse, mutect2, varscan2
- C1QB | c.137G>T p.G46V | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100152788; called by muse, mutect2, varscan2
- C1QTNF8 | c.104C>A p.P35H | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as rs762882674, COSV100116445; called by muse, mutect2, varscan2
- C1S | c.1445A>G p.E482G | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV100196668; called by muse, mutect2, varscan2
- C1orf127 | c.1881G>T p.Q627H | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV100983497; called by muse, mutect2, varscan2
- C1orf127 | c.921G>T p.E307D | Missense Mutation (SNP) | VAF 56/110 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100983498; called by muse, mutect2, varscan2
- C1orf194 | c.337G>T p.E113* (on ENST00000369948 / NM_001245025.3; = p.E101* on NM_001122961.2 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 48/103 reads (47%) | catalogued as rs763816794, COSV64049816; called by muse, mutect2, varscan2
- C2CD2 | c.417C>A p.F139L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100298266; called by muse, mutect2, varscan2
- C2CD3 | c.319C>A p.L107I | Missense Mutation (SNP) | VAF 56/120 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100076535; called by muse, mutect2, varscan2
- C2CD5 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1177770519, COSV100448884, COSV61725966; called by muse, mutect2, varscan2
- C2CD5 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1358127069, COSV61724153; called by muse, mutect2, varscan2
- C2orf16 | c.329G>T p.R110I | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.246); catalogued as COSV101284402, COSV68645958; called by muse, mutect2, varscan2
- C3 | c.3706G>A p.A1236T | Missense Mutation (SNP) | VAF 65/349 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1348868639, COSV99836901; called by muse, mutect2, varscan2
- C3 | c.2455G>T p.D819Y | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99836902; called by mutect2, varscan2
- C3orf33 | c.820A>G p.N274D (on ENST00000340171 / NM_001308229.2; = p.N231D on NM_173657.2) | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV100420115; called by muse, mutect2, varscan2
- C4BPA | c.472G>T p.D158Y | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100891240; called by mutect2, varscan2
- C4BPB | c.10dup p.W4Lfs*29 | Frame Shift Ins (INS) | VAF 30/63 reads (48%) | catalogued as rs1558074374; called by mutect2, varscan2
- C4orf17 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as rs1209919696, COSV99911000; called by muse, varscan2
- C5 | c.3436G>T p.A1146S | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.812); catalogued as COSV99798275; called by muse, mutect2, varscan2
- C5orf24 | c.146A>T p.K49I | Missense Mutation (SNP) | VAF 98/213 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV100574542; called by muse, mutect2, varscan2
- C5orf34 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.31); catalogued as COSV100175524; called by muse, mutect2, varscan2
- C6 | c.1095C>A p.Y365* | Nonsense Mutation (SNP) | VAF 12/112 reads (11%) | catalogued as COSV99667394; called by muse, mutect2, varscan2
- C6orf118 | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.452); catalogued as rs768763065, COSV57812657; called by mutect2, varscan2
- C6orf15 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as rs139294392; called by muse, mutect2, varscan2
- C6orf201 | c.31A>C p.N11H | Missense Mutation (SNP) | VAF 185/436 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100326611; called by muse, mutect2, varscan2
- C9 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV54679639; called by muse, mutect2, varscan2
- C9orf131 | c.2799G>T p.K933N | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV100398180; called by muse, mutect2
- C9orf64 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs781656702, COSV100123592; called by muse, mutect2, varscan2
- C9orf85 | c.167T>C p.V56A | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.846); catalogued as COSV100595092; called by muse, mutect2, varscan2
- CA11 | c.448A>G p.N150D | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.034); catalogued as COSV99320725; called by muse, mutect2
- CA3 | c.448G>T p.G150* | Nonsense Mutation (SNP) | VAF 17/76 reads (22%) | catalogued as COSV99570767; called by muse, mutect2, varscan2
- CAB39L | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 98/204 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100759597; called by muse, mutect2, varscan2
- CABIN1 | c.2740C>T p.R914* | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | catalogued as rs750920866, COSV99573606; called by muse, mutect2, varscan2
- CABLES2 | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as rs1429640918, COSV54156467; called by muse, mutect2, varscan2
- CACNA1B | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV53135708; called by muse, mutect2, varscan2
- CACNA1B | c.3526G>T p.D1176Y | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV99498435; called by muse, mutect2, varscan2
- CACNA1C | c.1336G>T p.D446Y | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100220054; called by muse, mutect2, varscan2
- CACNA1D | c.1520G>A p.R507H (on ENST00000350061 / NM_001128840.3; = p.R527H on NM_000720.4) | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as rs759521891, COSV55448678; called by muse, mutect2, varscan2
- CACNA1D | c.2713G>A p.A905T (on ENST00000350061 / NM_001128840.3; = p.A925T on NM_000720.4) | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs764701041, COSV99858964; called by muse, mutect2, varscan2
- CACNA1H | c.3889G>T p.D1297Y | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100673145; called by muse, mutect2
- CACNA2D3 | c.2181C>A p.F727L | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV99875014; called by muse, mutect2, varscan2
- CACNA2D4 | c.2412G>T p.Q804H | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.547); catalogued as COSV99766002; called by muse, mutect2, varscan2
- CACNB1 | c.1099C>A p.L367I | Missense Mutation (SNP) | VAF 27/231 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100703473; called by muse, mutect2, varscan2
- CACNG2 | c.635C>A p.A212D | Missense Mutation (SNP) | VAF 92/188 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs931411438, COSV100268891; called by muse, mutect2, varscan2
- CADPS | c.3249G>A p.W1083* | Nonsense Mutation (SNP) | VAF 21/91 reads (23%) | catalogued as COSV99339481; called by muse, mutect2, varscan2
- CADPS | c.1313C>A p.A438D | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV99339489; called by muse, mutect2, varscan2
- CALB2 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.264); catalogued as rs1375850883, COSV56940903; called by muse, varscan2
- CALB2 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); catalogued as rs748994795, COSV56938432; called by muse, varscan2
- CALCOCO2 | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 69/140 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs369142528; called by muse, mutect2, varscan2
- CALHM5 | c.928T>C p.*310Qext*6 | Nonstop Mutation (SNP) | VAF 52/95 reads (55%) | catalogued as COSV100635636; called by muse, mutect2, varscan2
- CALR3 | c.538C>A p.L180I | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.949); catalogued as COSV99522251; called by muse, mutect2, varscan2
- CALY | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.992); catalogued as COSV99428663; called by muse, mutect2, varscan2
- CAMK2D | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.136); catalogued as rs987657983, COSV56426469; called by muse, mutect2, varscan2
- CAMKK1 | c.1510G>A p.A504T | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.005); catalogued as COSV99340412; called by muse, mutect2, varscan2
- CAMKK2 | c.1440C>A p.S480R | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as rs776647930, COSV100243067; called by muse, mutect2, varscan2
- CAMKV | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99615738; called by muse, mutect2, varscan2
- CAMSAP1 | c.4491G>T p.K1497N | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56720602; called by muse, mutect2, varscan2
- CAMSAP2 | c.812G>T p.R271I (on ENST00000236925 / NM_001297707.2; = p.R260I on NM_203459.3) | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV99373696; called by muse, mutect2, varscan2
- CAMSAP2 | c.3838C>A p.P1280T (on ENST00000236925 / NM_001297707.2; = p.P1269T on NM_203459.3) | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.223); catalogued as COSV99373700; called by muse, mutect2, varscan2
- CAMTA1 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs1167802383, COSV57902763; called by muse, mutect2, varscan2
- CAMTA1 | c.3668G>T p.R1223I | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1459899218, COSV100351360; called by muse, mutect2, varscan2
- CAMTA1 | c.4412G>A p.S1471N | Missense Mutation (SNP) | VAF 75/205 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.89); catalogued as COSV100351361; called by muse, mutect2, varscan2
- CAMTA1 | c.4507A>G p.T1503A | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100351364; called by muse, mutect2, varscan2
- CAMTA2 | c.1969G>T p.A657S | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.97); catalogued as COSV100772674; called by muse, mutect2, varscan2
- CAND1 | c.1769T>A p.I590N | Missense Mutation (SNP) | VAF 56/225 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV101607332; called by muse, mutect2, varscan2
- CAND1 | c.2948G>A p.S983N | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV101607333; called by muse, mutect2
- CAND2 | c.1735C>T p.R579C (on ENST00000456430 / NM_001162499.2; = p.R486C on NM_012298.3) | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as rs750475682, COSV55987651; called by muse, mutect2, varscan2
- CANT1 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 58/279 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as rs747973861, COSV56606137; called by muse, mutect2, varscan2
- CANX | c.699G>T p.K233N | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV99910450; called by muse, mutect2, varscan2
- CAPG | c.111G>T p.E37D | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.047); catalogued as COSV99809503; called by muse, mutect2, varscan2
- CAPN1 | c.1400C>T p.A467V | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.034); catalogued as COSV54199665; called by muse, mutect2, varscan2
- CAPN13 | c.709A>G p.T237A | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.035); catalogued as COSV99700493; called by muse, mutect2
- CAPN5 | c.326G>A p.S109N (on ENST00000456580; = p.S69N on NM_004055.5) | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV99582327; called by muse, mutect2, varscan2
- CAPRIN2 | c.2630G>A p.G877E | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.182); catalogued as COSV99195546; called by muse, mutect2, varscan2
- CAPSL | c.382G>T p.D128Y | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1383174479, COSV101274291; called by muse, mutect2, varscan2
- CAPSL | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs199837654; called by muse, mutect2, varscan2
- CAPZA1 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs773856348, COSV54144396; called by muse, mutect2, varscan2
- CARD11 | c.740G>T p.R247I | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV101210782; called by muse, mutect2
- CARD11 | c.506C>T p.T169M | Missense Mutation (SNP) | VAF 74/139 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV62717031; called by muse, mutect2, varscan2
- CARD14 | c.1307C>T p.A436V | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV100712592; called by muse, mutect2, varscan2
- CARD14 | c.1675C>T p.R559W | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771451722, COSV100712593; called by muse, mutect2, varscan2
- CARD6 | c.172C>T p.R58W | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as rs911359307, COSV54565579; called by muse, mutect2, varscan2
- CARD6 | c.1763G>T p.R588M | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV99620980; called by muse, mutect2, varscan2
- CARF | c.1561A>T p.N521Y | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV100247750; called by mutect2, varscan2
- CARM1 | c.1414C>T p.P472S | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1277192410, COSV99450195; called by muse, mutect2, varscan2
- CARMIL1 | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 23/112 reads (21%) | catalogued as COSV61522110; called by muse, mutect2, varscan2
- CARMIL2 | c.887G>T p.S296I | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100576142; called by muse, mutect2, varscan2
- CARMIL2 | c.3583C>T p.R1195W | Missense Mutation (SNP) | VAF 27/230 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs757751829, COSV54666179; called by muse, mutect2, varscan2
- CASK | c.1534C>A p.H512N | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV100587411, COSV59363094; called by muse, mutect2, varscan2
- CASK | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 27/31 reads (87%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.811); catalogued as COSV100587412; called by muse, mutect2, varscan2
- CASKIN2 | c.412C>T p.Q138* | Nonsense Mutation (SNP) | VAF 16/80 reads (20%) | catalogued as COSV100395478; called by muse, mutect2, varscan2
- CASP1 | c.7+2T>C p.X3_splice | Splice Site (SNP) | VAF 23/119 reads (19%) | catalogued as COSV100782810; called by muse, mutect2, varscan2
- CASP3 | c.619C>T p.R207* | Nonsense Mutation (SNP) | VAF 9/59 reads (15%) | catalogued as rs757302190, COSV57725725; called by muse, mutect2, varscan2
- CASP4 | c.373-1G>T p.X125_splice | Splice Site (SNP) | VAF 10/132 reads (8%) | catalogued as COSV101274171; called by muse, mutect2
- CASP4 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV101274172; called by muse, mutect2, varscan2
- CASP8AP2 | c.2911C>T p.R971* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV52751001; called by muse, mutect2, varscan2
- CASR | c.1703C>T p.A568V (on ENST00000490131; = p.A645V on NM_000388.4) | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as CM124134, CM165824, COSV99949196; called by muse, mutect2, varscan2
- CAV2 | c.343T>G p.L115V | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99760828; called by muse, mutect2, varscan2
- CBFA2T3 | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs767127378, COSV99242084; called by mutect2, varscan2
- CBLB | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51424023; called by muse, mutect2, varscan2
- CC2D2A | c.3187T>G p.F1063V | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.44); PolyPhen benign (0.048); catalogued as COSV101052821; called by muse, mutect2, varscan2
- CCAR1 | c.324+2T>C p.X108_splice | Splice Site (SNP) | VAF 10/87 reads (11%) | catalogued as COSV99771193; called by muse, mutect2, varscan2
- CCAR1 | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as COSV56266888; called by muse, mutect2, varscan2
- CCAR1 | c.2545G>T p.D849Y | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as COSV99771194; called by muse, mutect2
- CCDC105 | c.629A>C p.K210T | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99479975; called by muse, mutect2, varscan2
- CCDC105 | c.885G>T p.L295F | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.214); catalogued as COSV99479978; called by muse, mutect2, varscan2
- CCDC125 | c.384A>C p.K128N | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.334); catalogued as rs1048592994, COSV101143660; called by muse, mutect2, varscan2
- CCDC141 | c.2170C>T p.R724* | Nonsense Mutation (SNP) | VAF 64/196 reads (33%) | catalogued as rs367700441, CM163738; called by muse, mutect2, varscan2
- CCDC142 | c.731G>T p.G244V | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99282253; called by muse, mutect2, varscan2
- CCDC15 | c.1289A>G p.D430G | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV100777001; called by muse, mutect2
- CCDC167 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV100982943; called by muse, mutect2, varscan2
- CCDC170 | c.1060G>T p.E354* | Nonsense Mutation (SNP) | VAF 10/67 reads (15%) | catalogued as COSV53340501, COSV99498598; called by muse, mutect2, varscan2
- CCDC171 | c.2879G>A p.R960H | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs368853808; called by muse, mutect2, varscan2
- CCDC18 | c.3103C>T p.R1035C (on ENST00000343253 / NM_001306076.1; = p.R1036C on NM_206886.4) | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs757538758, COSV100159768; called by muse, mutect2, varscan2
- CCDC18 | c.3797C>A p.A1266D (on ENST00000343253 / NM_001306076.1; = p.A1267D on NM_206886.4) | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100159769; called by muse, mutect2, varscan2
- CCDC180 | c.267G>T p.K89N | Missense Mutation (SNP) | VAF 78/139 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); catalogued as COSV100827028; called by muse, mutect2, varscan2
- CCDC181 | c.719C>A p.P240H | Missense Mutation (SNP) | VAF 45/223 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100890349; called by muse, mutect2, varscan2
- CCDC181 | c.387G>T p.E129D | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV100890350, COSV63155928; called by muse, mutect2, varscan2
- CCDC191 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 74/179 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.397); catalogued as COSV99878466; called by muse, mutect2, varscan2
- CCDC30 | c.1403A>G p.Q468R (on ENST00000340612; = p.Q425R on NM_001080850.3) | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.09); catalogued as COSV100501487; called by muse, mutect2, varscan2
- CCDC32 | c.239C>A p.S80Y | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63634628; called by muse, varscan2
- CCDC32 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 68/260 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs752914099, COSV100785979; called by muse, varscan2
- CCDC6 | c.1076C>A p.S359Y | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV99569635; called by muse, mutect2, varscan2
- CCDC6 | c.579A>C p.E193D | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.207); catalogued as COSV99569638; called by muse, varscan2
- CCDC60 | c.1532A>G p.D511G | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100555380; called by muse, mutect2, varscan2
7,357 further variants in this file (5,385 protein-altering or splice-affecting, 1,790 silent, 182 other) are not listed here.
